Gene-level copy-number profile of tumor specimen TCGA-F5-6813-01A from TCGA case TCGA-F5-6813, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of abdomen; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 70.2 years (25,651 days).
Specimen TCGA-F5-6813-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.47c00df1-0018-47aa-8028-bf37934a8e09.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-F5-6813-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f7b347c9-9863-49b7-83de-d866caad10f9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 14,200; copy number 2: 33,455; copy number 3: 9,550; copy number 4: 2,589; copy number 7: 12; copy number 23: 2; copy number 33: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-F5-6813-01A-11D-1825-01): tumor purity 0.67, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:6,703,883–6,721,960, 2 genes: AC007012.2, AC007012.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 21 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:39,626,740–39,747,291, 9 genes, copy number 23–33: PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7.
- chr20:13,995,369–16,053,197, 1 gene, copy number 7 (within-gene range 2–7): MACROD2.
- chr20:14,757,563–16,259,603, 11 genes, copy number 7 (within-gene range 4–7): RPS10P2, MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P, RNA5SP475, AL121584.1, ENSAP1, AL079338.1, AL161941.1, PPIAP17.

Autosomal genes at a single copy (total copy number 1): 11,815. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
